Somatic mutation profile of tumor specimen TCGA-04-1348-01A (aliquot TCGA-04-1348-01A-01W-0492-08) from TCGA case TCGA-04-1348, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 44.5 years (16,236 days).
Specimen TCGA-04-1348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 737326ac-1ac9-4d13-a71b-cfb9249c79b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1348-11A (Solid Tissue Normal), aliquot TCGA-04-1348-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a3fe9ad-b921-4df3-8072-ad171d2c8dd7

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 28, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFDN | c.4078A>G p.I1360V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV60039616; called by muse, mutect2, varscan2
- ANGPT1 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52433601; called by muse, mutect2, varscan2
- ARID4A | c.1399C>G p.P467A | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV62162476; called by muse, mutect2, varscan2
- CAD | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs377122535; called by muse, mutect2, varscan2
- CHERP | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52222915; called by muse, mutect2, varscan2
- EPB41L3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs372730881, COSV59446978; called by muse, mutect2, varscan2
- FAF2 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV56130131; called by muse, mutect2, varscan2
- GCLM | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV64686779; called by mutect2, varscan2
- GPHN | c.1955C>T p.P652L (on ENST00000315266 / NM_001377519.1; = p.P685L on NM_020806.5) | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs867392207, COSV59474876, COSV59485087; called by muse, mutect2, varscan2
- H3C11 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV100137941, COSV58901401; called by muse, mutect2, varscan2
- HHIP | c.1226C>A p.P409Q | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56837430; called by muse, mutect2, varscan2
- HM13 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.506); catalogued as rs200379311; called by muse, mutect2
- JPT1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1462423495; called by muse, mutect2
- LAMB2 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs544982873, COSV59731554; called by muse, mutect2
- MAOA | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58641565; called by muse, mutect2, varscan2
- MAP3K19 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1053619645, COSV59637205; called by muse, mutect2, varscan2
- NBEA | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59766911; called by muse, mutect2, varscan2
- OR14K1 | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51720676; called by muse, mutect2, varscan2
- OR56A1 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57362032; called by muse, mutect2, varscan2
- PADI2 | c.1719C>A p.F573L | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV64953305; called by muse, mutect2, varscan2
- RAB4A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 157/467 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs200242732, COSV64206945, COSV64207000; called by muse, mutect2, varscan2
- RFX1 | c.1386C>A p.H462Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260522590, COSV99586193; called by muse, mutect2
- RHOB | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV55355624; called by muse, mutect2, varscan2
- SCN10A | c.3692T>C p.I1231T | Missense Mutation (SNP) | VAF 155/412 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs147130891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STARD6 | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV57141580; called by muse, mutect2, varscan2
- TBCD | c.3245C>A p.S1082* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100833376; called by muse, mutect2, varscan2
- UNC13C | c.3537G>C p.E1179D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as COSV52850471; called by muse, mutect2, varscan2
- PDK4 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY5 | c.3399C>T p.S1133= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs375437829; called by muse, varscan2
- GBX2 | c.633C>T p.D211= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100103557; called by muse, mutect2, varscan2
- OR9G1 | c.846C>A p.P282= | Silent (SNP) | VAF 56/323 reads (17%) | catalogued as COSV100380440; called by muse, mutect2, varscan2
- UBQLN3 | c.843C>T p.A281= | Silent (SNP) | VAF 11/252 reads (4%) | catalogued as rs1436707476, COSV100293738; called by muse, mutect2
